Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHT, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHT-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 9.0 cm; no angio-invasion; no invasion of tunica albuginea; epididymis, rete testis and spermatic cord not present in the available slides.

Date of procurement (= date of orchidectomy):

ICD-O-3

Seminoma NOS 9061/3
Site @ Testis NOS C62.9

Op 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file c60b32f5-5634-4342-b9d9-694358f9f35d (TCGA-2G-AAHT.7ACA59FF-57F3-46E5-A01B-85F1E18674BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).